Somatic mutation profile of tumor specimen 0DIKK2 from CCDI case PBBVDR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Sertoli cell tumor, NOS; Tissue or organ of origin: Ovary; Age at diagnosis: 15.4 years (5,636 days).
Specimen 0DIKK2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a8d2d4a-2f58-4214-bea1-41b91aff0927.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIKJF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aaf63b99-59a8-4616-9d10-1e56323ffb08

The open-access MAF lists 10 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.5437G>A p.E1813K | Missense Mutation (SNP) | VAF 261/625 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as CM160050, COSV58615431, COSV58617855; called by muse, mutect2, varscan2
- ATF6B | c.2007G>T p.Q669H | Missense Mutation (SNP) | VAF 26/292 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); catalogued as COSV64351385; called by muse, mutect2
- MUC22 | c.3118A>G p.I1040V | Missense Mutation (SNP) | VAF 26/530 reads (5%) | SIFT tolerated (0.5); catalogued as rs1407758984; called by muse, mutect2
- PLD3 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 133/322 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.198); catalogued as rs780172579; called by muse, mutect2, varscan2
- TPR | c.4063C>T p.R1355W | Missense Mutation (SNP) | VAF 122/742 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs751924520, COSV66599357; called by muse, mutect2, varscan2
- ANO5 | c.2465A>T p.N822I | Missense Mutation (SNP) | VAF 26/590 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2
- DICER1 | c.4782_4789dup p.T1597Ifs*26 | Frame Shift Ins (INS) | VAF 132/413 reads (32%) | called by mutect2, varscan2
- PROSER3 | c.637A>G p.I213V | Missense Mutation (SNP) | VAF 194/436 reads (44%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF510 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 31/800 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- CROT | c.240+82G>A | Intron (SNP) | VAF 4/89 reads (4%) | called by muse, mutect2
